Somatic mutation profile of tumor specimen TCGA-WC-A882-01A (aliquot TCGA-WC-A882-01A-11D-A39W-08) from TCGA case TCGA-WC-A882, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Overlapping lesion of eye and adnexa; AJCC pathologic stage: Stage IIB; Age at diagnosis: 51.0 years (18,612 days).
Specimen TCGA-WC-A882-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e131768-e3b9-4188-8269-16348980f58d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WC-A882-10A (Blood Derived Normal), aliquot TCGA-WC-A882-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7172da0-fc8e-44b2-b724-caeb29479ad2

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SRSF2 | c.274_300del p.Y92_H100del | In Frame Del (DEL) | VAF 10/44 reads (23%) | hotspot (GDC flag); called by mutect2, pindel
- DGKK | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs985368837; called by muse, mutect2
- ERBB4 | c.2203G>T p.G735C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369649105, COSV53506429, COSV53551915; called by muse, mutect2
- PCDHGB4 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53919987; called by muse, mutect2, varscan2
- LAMA2 | c.4363T>C p.Y1455H | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SNTN | c.100A>T p.M34L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF511 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZNF518B | c.3101G>A p.C1034Y | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- LIMS1 | c.840C>G p.T280= | Silent (SNP) | VAF 16/74 reads (22%) | called by muse, mutect2
- SHF | c.1044C>T p.R348= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs1427750273; called by muse, mutect2, varscan2
- GABRE | c.784+1244C>A | Intron (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
